Somatic mutation profile of tumor specimen MBCProject_5953_T1_WES (aliquot MBCProject_5953_T1_WES_1) from CMI case MBCProject_5953, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.8 years (12,698 days).
Specimen MBCProject_5953_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5d21ee8-56cb-458b-b98b-32b452d05e80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5953_SALIVA (Saliva), aliquot MBCProject_5953_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/931beb74-3454-4c2a-be2e-600e4f2dd36e

The open-access MAF lists 83 somatic variants for this specimen: 44 protein-altering or splice-affecting, 19 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Intron 8, 5'UTR 5, 3'UTR 5, Nonsense Mutation 3, Frame Shift Ins 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV99566476; called by muse, mutect2, varscan2
- AKR1A1 | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 67/435 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61086843, COSV61087309; called by muse, mutect2, varscan2
- ASAP3 | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs370693470; called by muse, mutect2, varscan2
- CCDC87 | c.1991G>C p.G664A | Missense Mutation (SNP) | VAF 50/848 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV59578912; called by muse, mutect2
- CCDC87 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV59579904; called by muse, mutect2
- CPNE3 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 78/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52212036; called by muse, mutect2, varscan2
- H3C2 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 104/328 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV52518592, COSV52519945, COSV99451484; called by muse, mutect2, varscan2
- KRTAP20-1 | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | PolyPhen benign (0.037); catalogued as COSV100228781, COSV58168135; called by muse, mutect2, varscan2
- MTRR | c.548C>G p.S183* (on ENST00000264668; = p.S156* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | catalogued as rs919772858; called by muse, mutect2
- NOTCH1 | c.5528G>A p.W1843* | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | catalogued as COSV53036266; called by muse, mutect2
- NSMCE2 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 84/130 reads (65%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs140125530, COSV99786370; called by mutect2, varscan2
- OTOF | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99718637; called by muse, mutect2
- PLEC | c.6754G>A p.E2252K (on ENST00000322810 / NM_201380.4; = p.E2142K on NM_000445.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs782713908, COSV59640479; ClinVar: uncertain significance; called by muse, varscan2
- PPP1R26 | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63357242; called by mutect2, varscan2
- ZRSR2 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV100315195, COSV57063739; called by muse, mutect2
- ALDOB | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1H | c.4936G>T p.D1646Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCT4 | c.837G>C p.E279D | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COQ10A | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- FBXW5 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FER | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- GNMT | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- IMP3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- IZUMO1 | c.745C>G p.H249D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); called by mutect2, varscan2
- KDM4A | c.3019G>C p.D1007H | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- KIAA1217 | c.2589C>A p.F863L | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEFTY2 | c.612G>C p.Q204H | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MLH3 | c.2389C>G p.R797G | Missense Mutation (SNP) | VAF 103/461 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRX1 | c.15C>G p.H5Q | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2
- NRG1 | c.840G>C p.Q280H (on ENST00000405005 / NM_013964.5; = p.Q285H on NM_013956.5) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OTOA | c.2443G>C p.D815H (on ENST00000286149; = p.D801H on NM_144672.4) | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.283); called by muse, varscan2
- PDE3A | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PKHD1 | c.10285C>T p.P3429S | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- PRB4 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP6 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBM20 | c.3244dup p.L1082Pfs*12 | Frame Shift Ins (INS) | VAF 32/169 reads (19%) | called by mutect2, pindel, varscan2
- RIMBP3B | c.4581G>T p.R1527S | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.012); called by mutect2, varscan2
- RNF175 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSC5D | c.1675C>G p.H559D | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUPT20HL1 | c.2515C>A p.L839I | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TCP10L | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- XRCC6 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, varscan2
- ZNF614 | c.1422G>C p.E474D | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2
- ABHD11 | c.234C>T p.S78= | Silent (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- BCL9 | c.291G>T p.G97= | Silent (SNP) | VAF 17/239 reads (7%) | called by muse, mutect2
- CILP2 | c.2823C>T p.L941= | Silent (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- EPS8L2 | c.531C>T p.G177= | Silent (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- L1CAM | c.2709G>A p.S903= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs146224667; called by muse, mutect2, varscan2
- LRRC18 | c.780T>G p.S260= | Silent (SNP) | VAF 42/172 reads (24%) | called by muse, mutect2, varscan2
- MAJIN | c.513C>G p.L171= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs1367152047; called by muse, mutect2, varscan2
- NWD2 | c.522C>G p.L174= | Silent (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- OPRL1 | c.954C>G p.L318= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- PLP1 | c.798C>T p.A266= | Silent (SNP) | VAF 76/264 reads (29%) | catalogued as rs955050340; called by muse, varscan2
- RPS6KA4 | c.2100G>A p.S700= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs745655854; called by mutect2, varscan2
- S100A2 | c.222G>A p.Q74= | Silent (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- SEC14L5 | c.546G>A p.T182= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs192935938, COSV99229472; called by muse, mutect2, varscan2
- SLC5A5 | c.1044C>T p.Y348= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- STK36 | c.471G>C p.L157= | Silent (SNP) | VAF 28/98 reads (29%) | called by mutect2, varscan2
- STK4 | c.450C>T p.I150= | Silent (SNP) | VAF 22/148 reads (15%) | called by muse, varscan2
- SYCP2L | c.1041G>A p.P347= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as rs1032377815, COSV51652159; called by muse, mutect2, varscan2
- UCHL5 | c.168C>T p.F56= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- XIRP2 | c.9753G>A p.E3251= (on ENST00000628543; = p.E3426= on NM_152381.6) | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- ACBD4 | c.*32G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs990082262; called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 8/48 reads (17%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- CDK20 | c.*19G>A | 3'UTR (SNP) | VAF 43/169 reads (25%) | catalogued as rs747016520; called by muse, mutect2, varscan2
- CTSF | c.-10C>T | 5'UTR (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- FTH1 | chr11:61968498 C>G | 5'Flank (SNP) | VAF 74/175 reads (42%) | called by muse, mutect2, varscan2
- GABRG2 | c.1042+32C>T | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2
- MUC3A | c.-80G>A | 5'UTR (SNP) | VAF 6/34 reads (18%) | catalogued as rs1400014342; called by muse, mutect2, varscan2
- NPDC1 | c.113-31G>C | Intron (SNP) | VAF 10/55 reads (18%) | catalogued as COSV61911184; called by muse, mutect2, varscan2
- P2RX5 | c.*8C>G | 3'UTR (SNP) | VAF 46/208 reads (22%) | called by muse, mutect2, varscan2
- PDZRN4 | c.844-68454G>A | Intron (SNP) | VAF 35/159 reads (22%) | catalogued as COSV54214054; called by muse, mutect2, varscan2
- PLEC | c.524-5093G>A | Intron (SNP) | VAF 86/488 reads (18%) | catalogued as rs535379967, COSV100515309; called by muse, mutect2, varscan2
- PPIF | c.-1G>A | 5'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs1017802752; called by muse, mutect2
- PRECSIT | n.648G>A | RNA (SNP) | VAF 46/141 reads (33%) | called by muse, mutect2, varscan2
- PRKCG | c.*33C>A | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99669693; called by muse, mutect2, varscan2
- RALGAPA2 | c.*83G>C | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- RPL23A | c.-17G>C | 5'UTR (SNP) | VAF 78/580 reads (13%) | catalogued as rs891509006, COSV52644667; called by muse, mutect2, varscan2
- STAT4 | c.273+14770C>T | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, varscan2
- SUGT1P3 | n.215-1349G>A | Intron (SNP) | VAF 34/158 reads (22%) | catalogued as rs1378316419; called by muse, varscan2
- TRIP12 | c.99-862C>T | Intron (SNP) | VAF 26/108 reads (24%) | catalogued as rs749078387; called by muse, mutect2, varscan2
- UNC93B1 | c.-21G>A | 5'UTR (SNP) | VAF 8/49 reads (16%) | catalogued as rs1428035135; called by muse, mutect2
